Somatic mutation profile of tumor specimen 0DTDVW from CCDI case PBCJTT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.4 years (1,225 days).
Specimen 0DTDVW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e78e8f9-62b8-4597-8fae-76521a4199fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTDVX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e9d84aa-1482-4349-9d42-e3761a9ea126

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH15 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 176/653 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as rs767215353; called by muse, mutect2, varscan2
- LRP2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs763860226, COSV55542058; called by muse, mutect2, varscan2
- TMEM186 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201350921; called by muse, mutect2, varscan2
- CEP152 | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 131/479 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CXCR1 | c.780G>T p.L260= | Silent (SNP) | VAF 98/370 reads (26%) | called by mutect2, varscan2
- ZNF577 | c.534A>G p.R178= | Silent (SNP) | VAF 107/235 reads (46%) | called by muse, varscan2
